Gene-level copy-number profile of tumor specimen TCGA-AA-A022-01A from TCGA case TCGA-AA-A022, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 88.8 years (32,446 days).
Specimen TCGA-AA-A022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e6d38cbe-34c8-4f08-8cfd-8b14fdb4b53f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A022-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1b76733-85c6-4f44-bbc9-fafa05488974

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,658; copy number 2: 51,542; copy number 3: 4,294; copy number 4: 2,177; copy number 5: 145.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A022-01A-21D-A080-01): tumor purity 0.71, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 145 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–7,961,224, 139 genes, copy number 5 (broad region; genes not listed).
- chr9:8,700,595–9,091,245, 6 genes, copy number 5: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.

Autosomal genes at a single copy (total copy number 1): 1,658. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
